CCDI case PBCKMI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/7f86712d-0b72-4262-b89f-ebf0a509ed72

Demographics
Sex at birth: female.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.1 years (6,240 days).

Biospecimens (3 samples)
- Sample 0DUETH: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DUETS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DUNPB: Tissue type: Tumor; Specimen type: Solid Tissue.
